Somatic mutation profile of tumor specimen MMRF_2642_1_BM_CD138pos (aliquot MMRF_2642_1_BM_CD138pos_T1_KHS5U_L13411) from MMRF case MMRF_2642, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.3 years (21,664 days).
Specimen MMRF_2642_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ed10803-6221-412d-85d8-1c9f2360fb28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2642_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2642_1_PB_WBC_C3_KHS5U_L13410; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a13b6ff5-b609-494c-abd6-9c1947b3eeaf

The open-access MAF lists 229 somatic variants for this specimen: 89 protein-altering or splice-affecting, 23 silent, 117 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, 3'UTR 66, Intron 35, Silent 23, Nonsense Mutation 7, 5'UTR 6, 3'Flank 4, RNA 4, Frame Shift Ins 2, Translation Start Site 2, 5'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 53/153 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC068580.4 | c.4C>T p.Q2* | Nonsense Mutation (SNP) | VAF 3/40 reads (8%) | catalogued as rs1355247629; called by muse, mutect2
- AGBL1 | c.2764C>T p.Q922* | Nonsense Mutation (SNP) | VAF 38/118 reads (32%) | catalogued as rs779553844; called by muse, mutect2, varscan2
- ASAP1 | c.1786C>T p.P596S | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs944068676, COSV63054406; called by muse, mutect2, varscan2
- CHCHD6 | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 75/278 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as rs1428643056; called by muse, mutect2, varscan2
- CNTNAP1 | c.2906T>G p.F969C | Missense Mutation (SNP) | VAF 74/221 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.195); catalogued as COSV99226432; called by muse, mutect2, varscan2
- CSMD2 | c.472G>T p.G158C | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99596547; called by muse, mutect2, varscan2
- CSPG5 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 45/159 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1246833442, COSV53129907; called by muse, mutect2, varscan2
- ERC2 | c.2171C>T p.A724V | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as rs775270120, COSV55604163; called by muse, mutect2, varscan2
- GBP6 | c.1699_1701del p.K567del | In Frame Del (DEL) | VAF 52/146 reads (36%) | catalogued as rs755314330; called by pindel, varscan2
- GPR149 | c.523T>A p.F175I | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs779771096; called by muse, mutect2, varscan2
- HPS4 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 133/320 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as COSV100404219; called by muse, mutect2, varscan2
- JPH1 | c.861C>G p.N287K | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV100646643; called by muse, mutect2
- KRT23 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs1312198460; called by muse, mutect2, varscan2
- MAN2C1 | c.397A>T p.R133W | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV51237286; called by muse, mutect2, varscan2
- MAP7D1 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs780310575, COSV60214922; called by muse, mutect2, varscan2
- MEFV | c.199G>A p.V67M | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422054832; called by muse, mutect2, varscan2
- NOBOX | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99779608; called by muse, mutect2, varscan2
- NPR2 | c.2410C>T p.R804C | Missense Mutation (SNP) | VAF 131/258 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs759694185; called by muse, mutect2, varscan2
- NTRK3 | c.2237A>T p.K746M (on ENST00000360948 / NM_001012338.2; = p.K732M on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62295703, COSV62301322; called by muse, mutect2, varscan2
- PAPPA2 | c.2239G>T p.G747* | Nonsense Mutation (SNP) | VAF 206/384 reads (54%) | catalogued as COSV62773554; called by muse, mutect2, varscan2
- PCLO | c.12232C>T p.R4078C | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs150669313, COSV100428830; called by muse, mutect2, varscan2
- PPL | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374651720, COSV62046761; called by muse, mutect2, varscan2
- PRKCG | c.1333C>A p.H445N | Missense Mutation (SNP) | VAF 96/364 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1311765439; called by muse, mutect2, varscan2
- RDH11 | c.86C>G p.S29C | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV67282748; called by muse, mutect2, varscan2
- RNF146 | c.519A>G p.I173M (on ENST00000368314 / NM_001242850.2; = p.I172M on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/198 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs747022811; called by muse, mutect2, varscan2
- ROBO1 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 160/573 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs757651792; called by muse, mutect2, varscan2
- RPE65 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 160/481 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV52012757; called by muse, mutect2, varscan2
- RTL1 | c.3514C>T p.R1172C | Missense Mutation (SNP) | VAF 92/236 reads (39%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs561030751, COSV101128114; called by muse, mutect2, varscan2
- SLC26A9 | c.1580A>T p.Q527L | Missense Mutation (SNP) | VAF 79/285 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV61603165, COSV61604928; called by muse, mutect2, varscan2
- SLC27A5 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1568627959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC45A2 | c.1307G>A p.S436N | Missense Mutation (SNP) | VAF 94/351 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as COSV99672775; called by muse, mutect2, varscan2
- SNX25 | c.2260C>A p.P754T | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.833); catalogued as rs765032786; called by muse, mutect2, varscan2
- SP140 | c.2015dup p.R673Efs*9 | Frame Shift Ins (INS) | VAF 75/186 reads (40%) | catalogued as rs746109620; called by mutect2, varscan2
- STAB1 | c.4894C>G p.L1632V | Missense Mutation (SNP) | VAF 82/323 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.079); catalogued as rs1166299058; called by muse, mutect2, varscan2
- SUFU | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.428); catalogued as rs1403040084, COSV64014990; called by muse, mutect2, varscan2
- YWHAE | c.99G>C p.M33I | Missense Mutation (SNP) | VAF 209/533 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.038); catalogued as rs753099645; called by muse, mutect2, varscan2
- ZNF354A | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 68/269 reads (25%) | catalogued as rs201156739, COSV59984026; called by muse, mutect2, varscan2
- AFAP1L2 | c.2181G>T p.E727D | Missense Mutation (SNP) | VAF 107/288 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AFF2 | c.2172G>T p.Q724H | Missense Mutation (SNP) | VAF 198/252 reads (79%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AKAP13 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 48/243 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AKAP13 | c.5381T>A p.F1794Y (on ENST00000394518 / NM_007200.5; = p.F1798Y on NM_006738.6) | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- AKAP13 | c.5382C>A p.F1794L (on ENST00000394518 / NM_007200.5; = p.F1798L on NM_006738.6) | Missense Mutation (SNP) | VAF 100/313 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ARHGAP30 | c.2454A>C p.E818D | Missense Mutation (SNP) | VAF 263/453 reads (58%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ASCL3 | c.486A>T p.K162N | Missense Mutation (SNP) | VAF 203/495 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- C4orf45 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 115/344 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.112); called by muse, varscan2
- C4orf45 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 112/344 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); called by muse, varscan2
- CARS1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC169 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 206/306 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CDC20 | c.972G>C p.L324F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CDC37L1 | c.944C>A p.T315K | Missense Mutation (SNP) | VAF 168/797 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CNTLN | c.2030G>A p.S677N | Missense Mutation (SNP) | VAF 43/240 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- DCTN2 | c.272A>C p.E91A (on ENST00000548249 / NM_001261413.2; = p.E96A on NM_006400.4) | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- EVI5L | c.1642G>T p.E548* | Nonsense Mutation (SNP) | VAF 56/263 reads (21%) | called by muse, mutect2, varscan2
- FCN2 | c.472G>T p.D158Y | Missense Mutation (SNP) | VAF 66/290 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FGFBP2 | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 71/209 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- FSIP1 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 138/251 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- HRH3 | c.384C>G p.I128M | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INO80 | c.1154T>G p.L385R | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- INTS1 | c.5831A>T p.N1944I | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.094); called by muse, mutect2
- ISY1-RAB43 | c.839G>A p.R280K | Missense Mutation (SNP) | VAF 58/235 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- JCAD | c.1627T>C p.S543P | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KRTAP16-1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LEMD3 | c.1401T>G p.S467R | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K19 | c.2436A>C p.E812D | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- MEF2C | c.935dup p.S313Ifs*15 | Frame Shift Ins (INS) | VAF 133/509 reads (26%) | called by mutect2, pindel, varscan2
- MFSD14A | c.310T>C p.F104L | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- MST1 | c.2153T>C p.I718T | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH2 | c.3625C>A p.L1209I | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- NEXMIF | c.4033A>T p.M1345L | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCDH10 | c.1978G>T p.V660L | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PEF1 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 155/375 reads (41%) | called by muse, mutect2, varscan2
- PLAGL2 | c.1121C>T p.S374F | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- PLEKHF2 | c.470T>C p.V157A | Missense Mutation (SNP) | VAF 88/255 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PLEKHG4B | c.3658C>A p.H1220N (on ENST00000283426; = p.H1576N on NM_052909.5) | Missense Mutation (SNP) | VAF 66/250 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- PTPN3 | c.539A>G p.Q180R | Missense Mutation (SNP) | VAF 77/308 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RABEPK | c.250T>A p.L84M | Missense Mutation (SNP) | VAF 60/290 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SCN1A | c.2357C>A p.A786D (on ENST00000303395 / NM_001202435.3; = p.A775D on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SKOR2 | c.1184T>A p.L395Q | Missense Mutation (SNP) | VAF 61/215 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- SP100 | c.2621T>C p.I874T | Missense Mutation (SNP) | VAF 117/340 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCHHL1 | c.2203C>G p.Q735E | Missense Mutation (SNP) | VAF 91/336 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TTLL11 | c.2023A>G p.S675G | Missense Mutation (SNP) | VAF 205/281 reads (73%) | SIFT tolerated (0.11); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TXNDC5 | c.1177-8_1205del p.X393_splice | Splice Site (DEL) | VAF 34/187 reads (18%) | called by mutect2, pindel
- UCP2 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- UNC93A | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- VSTM1 | c.265A>T p.K89* | Nonsense Mutation (SNP) | VAF 90/308 reads (29%) | called by muse, varscan2
- ZNF221 | c.1638A>C p.K546N | Missense Mutation (SNP) | VAF 112/389 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZNF552 | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 67/288 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF707 | c.390C>A p.D130E | Missense Mutation (SNP) | VAF 18/311 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ABCC11 | c.2275C>T p.L759= | Silent (SNP) | VAF 19/55 reads (35%) | called by muse, mutect2
- ASTN1 | c.1806C>T p.R602= | Silent (SNP) | VAF 45/180 reads (25%) | catalogued as rs370987824; called by muse, mutect2, varscan2
- BRAT1 | c.1389C>T p.S463= | Silent (SNP) | VAF 39/71 reads (55%) | catalogued as rs1162576672; called by muse, mutect2, varscan2
- CDC42 | c.529C>T p.L177= | Silent (SNP) | VAF 65/141 reads (46%) | catalogued as rs759623419; called by muse, mutect2, varscan2
- CHRM5 | c.867C>T p.G289= | Silent (SNP) | VAF 64/244 reads (26%) | called by muse, mutect2, varscan2
- DAAM1 | c.1437G>A p.E479= | Silent (SNP) | VAF 55/143 reads (38%) | called by muse, mutect2, varscan2
- FBN3 | c.6462C>T p.D2154= | Silent (SNP) | VAF 51/179 reads (28%) | catalogued as rs776542955, COSV54456098; called by muse, mutect2, varscan2
- HNF1A | c.309G>A p.V103= | Silent (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- HRH3 | c.642C>T p.V214= | Silent (SNP) | VAF 92/272 reads (34%) | catalogued as rs768042321; called by muse, mutect2, varscan2
- IGKV1-5 | c.339T>C p.Y113= | Silent (SNP) | VAF 35/61 reads (57%) | catalogued as rs775143159; called by muse, mutect2
- MUC16 | c.42399T>G p.P14133= | Silent (SNP) | VAF 13/47 reads (28%) | called by muse, mutect2, varscan2
- PDE1B | c.1395C>T p.P465= | Silent (SNP) | VAF 52/133 reads (39%) | catalogued as rs772714171; called by muse, mutect2, varscan2
- RNASET2 | c.36C>T p.G12= | Silent (SNP) | VAF 40/100 reads (40%) | called by muse, mutect2, varscan2
- SCGB1D2 | c.63C>T p.A21= | Silent (SNP) | VAF 44/139 reads (32%) | catalogued as rs754124729; called by muse, mutect2, varscan2
- SCN1A | c.2358C>T p.A786= (on ENST00000303395 / NM_001202435.3; = p.A775= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs1350281689; called by muse, mutect2, varscan2
- SCRIB | c.174G>C p.L58= | Silent (SNP) | VAF 62/156 reads (40%) | called by muse, mutect2, varscan2
- SLC22A2 | c.363C>T p.P121= | Silent (SNP) | VAF 87/232 reads (38%) | called by muse, mutect2, varscan2
- SLC25A31 | c.447C>G p.A149= | Silent (SNP) | VAF 38/139 reads (27%) | called by muse, mutect2, varscan2
- SLC39A12 | c.957A>T p.I319= | Silent (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- SPTA1 | c.1398C>T p.D466= | Silent (SNP) | VAF 72/151 reads (48%) | catalogued as rs763562631, COSV63752131; called by muse, mutect2, varscan2
- SYNGAP1 | c.2631G>A p.L877= | Silent (SNP) | VAF 83/233 reads (36%) | called by muse, mutect2, varscan2
- TMBIM1 | c.57C>A p.G19= | Silent (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.1044G>A p.P348= (on ENST00000252463; = p.P403= on NM_032805.3) | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs746422336, COSV52971269; called by muse, mutect2, varscan2
- ABR | c.1561+84C>A | Intron (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- AC093802.1 | n.1914+8293G>A | Intron (SNP) | VAF 131/362 reads (36%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-4999G>A | Intron (SNP) | VAF 54/231 reads (23%) | called by muse, mutect2, varscan2
- ACACB | c.5023-493G>A | Intron (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- AFF2 | c.*5164C>A | 3'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- AKR1C1 | c.85-15T>C | Intron (SNP) | VAF 114/297 reads (38%) | called by muse, mutect2, varscan2
- AKT1 | c.288-57C>T | Intron (SNP) | VAF 62/147 reads (42%) | catalogued as rs553824342; called by muse, varscan2
- AKT1S1 | c.-7-1263C>G | Intron (SNP) | VAF 73/127 reads (57%) | called by muse, mutect2, varscan2
- ALDH4A1 | c.*41+36C>G | Intron (SNP) | VAF 18/32 reads (56%) | called by muse, mutect2, varscan2
- AP001496.2 | n.934A>G | RNA (SNP) | VAF 10/296 reads (3%) | called by muse, mutect2
- APBA1 | c.-10G>A | 5'UTR (SNP) | VAF 63/282 reads (22%) | catalogued as rs1037796582; called by muse, mutect2, varscan2
- ATP11AUN | n.1418C>T | RNA (SNP) | VAF 39/59 reads (66%) | called by muse, mutect2, varscan2
- ATP8A1 | c.264+65A>G | Intron (SNP) | VAF 163/416 reads (39%) | catalogued as rs912871817; called by muse, mutect2, varscan2
- BAZ2A | c.*1912T>G | 3'UTR (SNP) | VAF 4/97 reads (4%) | called by muse, mutect2
- BMP6 | c.*1180_*1186del | 3'UTR (DEL) | VAF 42/129 reads (33%) | called by mutect2, pindel, varscan2
- C6orf62 | chr6:24719951 A>G | 5'Flank (SNP) | VAF 133/379 reads (35%) | called by muse, mutect2, varscan2
- CCND2 | c.*3001T>A | 3'UTR (SNP) | VAF 48/139 reads (35%) | called by muse, mutect2, varscan2
- CD2AP | c.-117G>C | 5'UTR (SNP) | VAF 15/38 reads (39%) | called by muse, mutect2, varscan2
- CD48 | c.385+574A>G | Intron (SNP) | VAF 91/160 reads (57%) | called by muse, mutect2, varscan2
- CD74 | c.881-48G>A | Intron (SNP) | VAF 93/435 reads (21%) | called by muse, mutect2, varscan2
- CENATAC | chr11:118996261 C>A | 5'Flank (SNP) | VAF 54/159 reads (34%) | called by muse, mutect2, varscan2
- CFAP92 | c.*545A>C | 3'UTR (SNP) | VAF 35/126 reads (28%) | called by muse, mutect2, varscan2
- CGB7 | c.-1927G>T | 5'UTR (SNP) | VAF 3/15 reads (20%) | called by muse, mutect2
- CRYBB3 | c.*115C>T | 3'UTR (SNP) | VAF 91/231 reads (39%) | called by muse, mutect2, varscan2
- CSMD1 | chr8:2936902 G>A | 3'Flank (SNP) | VAF 56/137 reads (41%) | catalogued as rs143233312; called by muse, mutect2, varscan2
- CTPS1 | c.1006-71T>C | Intron (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- CYP2U1 | c.*2137C>T | 3'UTR (SNP) | VAF 35/118 reads (30%) | called by muse, mutect2, varscan2
- DBT | c.*2007C>G | 3'UTR (SNP) | VAF 40/128 reads (31%) | catalogued as rs1208422674; called by muse, mutect2, varscan2
- DCUN1D3 | c.*1362T>C | 3'UTR (SNP) | VAF 34/67 reads (51%) | catalogued as rs557086730; called by muse, mutect2, varscan2
- DDX39B | c.-2-34A>G | Intron (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- EFEMP1 | c.-7-23G>C | Intron (SNP) | VAF 166/418 reads (40%) | called by muse, mutect2, varscan2
- EIF2AK2 | c.*778A>G | 3'UTR (SNP) | VAF 24/69 reads (35%) | catalogued as rs892043154; called by muse, mutect2, varscan2
- F2RL1 | c.*98C>A | 3'UTR (SNP) | VAF 100/306 reads (33%) | called by muse, mutect2, varscan2
- F2RL1 | c.*99C>T | 3'UTR (SNP) | VAF 95/294 reads (32%) | called by muse, mutect2, varscan2
- FAAP100 | c.1404-39T>C | Intron (SNP) | VAF 86/201 reads (43%) | called by muse, mutect2, varscan2
- FAM210B | c.186+1301C>T | Intron (SNP) | VAF 119/287 reads (41%) | called by muse, mutect2, varscan2
- FAM220CP | n.377G>A | RNA (SNP) | VAF 35/172 reads (20%) | called by muse, mutect2, varscan2
- FAN1 | c.1234+488C>T | Intron (SNP) | VAF 36/151 reads (24%) | called by muse, mutect2, varscan2
- FIBIN | c.-30T>A | 5'UTR (SNP) | VAF 29/77 reads (38%) | called by muse, mutect2, varscan2
- FLRT3 | c.*411C>A | 3'UTR (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- FMO2 | c.*1359T>A | 3'UTR (SNP) | VAF 62/203 reads (31%) | called by muse, mutect2, varscan2
- GABRA2 | c.187+21541C>G | Intron (SNP) | VAF 44/104 reads (42%) | called by muse, mutect2, varscan2
- GFRA2 | chr8:21692399 del C | 3'Flank (DEL) | VAF 43/249 reads (17%) | called by mutect2, pindel, varscan2
- GLIS3 | c.*2840del | 3'UTR (DEL) | VAF 72/156 reads (46%) | catalogued as rs142133114; ClinVar: likely benign; called by mutect2, varscan2
- GPR3 | c.*539C>T | 3'UTR (SNP) | VAF 38/74 reads (51%) | called by muse, mutect2, varscan2
- HGF | c.*711G>C | 3'UTR (SNP) | VAF 27/86 reads (31%) | called by muse, mutect2, varscan2
- HNF4G | chr8:75565856 T>C | 3'Flank (SNP) | VAF 24/57 reads (42%) | called by muse, mutect2, varscan2
- IGHV3-7 | c.-14A>G | 5'UTR (SNP) | VAF 114/164 reads (70%) | catalogued as rs782024354; called by muse, varscan2
- IGSF23 | c.-10C>T | 5'UTR (SNP) | VAF 196/727 reads (27%) | catalogued as rs1002658159; called by muse, mutect2, varscan2
- ITPRIP | c.*1716G>T | 3'UTR (SNP) | VAF 71/180 reads (39%) | called by muse, mutect2, varscan2
- KLHL7 | c.*249A>T | 3'UTR (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
- LARS1 | c.2090+77del | Intron (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel
- LIMS2 | c.803-30G>A | Intron (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- LIN7C | c.*1102T>G | 3'UTR (SNP) | VAF 41/102 reads (40%) | called by muse, mutect2, varscan2
- LINGO1-AS1 | n.412G>C | RNA (SNP) | VAF 41/178 reads (23%) | called by muse, mutect2, varscan2
- MAP7 | c.*30T>A | 3'UTR (SNP) | VAF 89/243 reads (37%) | called by muse, mutect2, varscan2
- MAPKBP1 | c.*2118C>T | 3'UTR (SNP) | VAF 167/610 reads (27%) | called by muse, mutect2, varscan2
- MEGF6 | c.*156C>T | 3'UTR (SNP) | VAF 20/76 reads (26%) | catalogued as rs1015017288; called by muse, mutect2, varscan2
- NCOA3 | c.*3178A>G | 3'UTR (SNP) | VAF 36/115 reads (31%) | called by muse, mutect2, varscan2
- NCOA3 | c.*3179A>T | 3'UTR (SNP) | VAF 37/117 reads (32%) | called by muse, mutect2, varscan2
- NDE1 | chr16:15726826 C>T | 3'Flank (SNP) | VAF 72/156 reads (46%) | called by muse, mutect2, varscan2
- NEK1 | c.1020+301T>G | Intron (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- NFIB | c.*724A>G | 3'UTR (SNP) | VAF 23/41 reads (56%) | catalogued as rs1372638181; called by muse, mutect2, varscan2
- NMNAT2 | c.*734C>T | 3'UTR (SNP) | VAF 60/96 reads (63%) | catalogued as rs201073992; called by muse, varscan2
- NOVA1 | c.*2160A>C | 3'UTR (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- OLFML1 | c.*1060G>T | 3'UTR (SNP) | VAF 39/118 reads (33%) | called by muse, mutect2, varscan2
- OR4C11 | c.*183G>T | 3'UTR (SNP) | VAF 51/102 reads (50%) | called by muse, mutect2, varscan2
- PBX3 | c.201-141G>C | Intron (SNP) | VAF 52/199 reads (26%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+4706G>A | Intron (SNP) | VAF 79/296 reads (27%) | catalogued as rs782245937; called by muse, mutect2, varscan2
- PEA15 | c.*1583G>A | 3'UTR (SNP) | VAF 112/214 reads (52%) | called by muse, mutect2, varscan2
- PERM1 | c.*407G>A | 3'UTR (SNP) | VAF 55/190 reads (29%) | called by muse, mutect2, varscan2
- PLA2G4D | c.472-75G>T | Intron (SNP) | VAF 28/85 reads (33%) | called by muse, mutect2, varscan2
- PLEKHA1 | c.*539G>C | 3'UTR (SNP) | VAF 73/182 reads (40%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.*1912T>G | 3'UTR (SNP) | VAF 21/66 reads (32%) | catalogued as rs1245184649; called by muse, mutect2, varscan2
- PLIN4 | c.*320G>C | 3'UTR (SNP) | VAF 30/85 reads (35%) | called by muse, mutect2, varscan2
- POLR1A | c.*558G>C | 3'UTR (SNP) | VAF 86/238 reads (36%) | called by muse, mutect2, varscan2
- PRLR | c.*1711T>C | 3'UTR (SNP) | VAF 48/153 reads (31%) | called by muse, mutect2, varscan2
- PSD4 | c.*391T>C | 3'UTR (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- PTK7 | c.368-183C>T | Intron (SNP) | VAF 28/69 reads (41%) | catalogued as rs1028837348; called by muse, mutect2, varscan2
- PWWP3B | c.*1338C>T | 3'UTR (SNP) | VAF 75/195 reads (38%) | called by muse, mutect2, varscan2
- PXYLP1 | c.*208C>T | 3'UTR (SNP) | VAF 55/195 reads (28%) | called by muse, mutect2, varscan2
- RAB40C | c.*1452T>A | 3'UTR (SNP) | VAF 73/178 reads (41%) | called by muse, mutect2, varscan2
- RBBP9 | c.*719C>A | 3'UTR (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- RBM22 | c.747-43T>G | Intron (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2, varscan2
- RDH10 | c.*89A>T | 3'UTR (SNP) | VAF 39/121 reads (32%) | called by muse, mutect2, varscan2
- RELA | c.664+85G>A | Intron (SNP) | VAF 104/267 reads (39%) | called by muse, mutect2, varscan2
- RUFY3 | c.*1437T>G | 3'UTR (SNP) | VAF 43/91 reads (47%) | called by muse, mutect2, varscan2
- SDC4 | c.*1683G>A | 3'UTR (SNP) | VAF 64/181 reads (35%) | catalogued as rs963155804; called by muse, mutect2, varscan2
- SDHAF4 | c.*386del | 3'UTR (DEL) | VAF 6/30 reads (20%) | catalogued as rs759872733, COSV65085169; called by pindel, varscan2
- SERP1 | c.*1826T>A | 3'UTR (SNP) | VAF 57/236 reads (24%) | called by muse, mutect2, varscan2
- SESN3 | c.*2229C>A | 3'UTR (SNP) | VAF 61/148 reads (41%) | called by muse, mutect2
- SESN3 | c.*2227C>A | 3'UTR (SNP) | VAF 61/145 reads (42%) | called by muse, mutect2
- SLC1A2 | c.*3460A>T | 3'UTR (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- SNX22 | c.*1814del | 3'UTR (DEL) | VAF 58/220 reads (26%) | called by mutect2, pindel, varscan2
- SSU72 | c.225-398G>C | Intron (SNP) | VAF 107/315 reads (34%) | called by muse, mutect2, varscan2
- STAT1 | c.1582+20T>C | Intron (SNP) | VAF 56/123 reads (46%) | called by muse, mutect2, varscan2
- STEAP2 | c.*1308C>T | 3'UTR (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- SUFU | c.*2897C>T | 3'UTR (SNP) | VAF 30/97 reads (31%) | called by muse, mutect2, varscan2
- TBC1D15 | c.*1052G>C | 3'UTR (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- TFCP2L1 | c.*6150G>A | 3'UTR (SNP) | VAF 35/100 reads (35%) | called by muse, mutect2, varscan2
- TGFBI | c.913+105T>G | Intron (SNP) | VAF 18/75 reads (24%) | called by muse, mutect2
- TMC6 | c.*134A>C | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- TMSB4X | c.*244del | 3'UTR (DEL) | VAF 57/103 reads (55%) | called by mutect2, pindel, varscan2
- TRDN | c.484+1364T>A | Intron (SNP) | VAF 74/180 reads (41%) | called by muse, mutect2, varscan2
- TSPAN18 | c.*1322A>T | 3'UTR (SNP) | VAF 97/237 reads (41%) | called by muse, mutect2, varscan2
- TSPAN9 | c.*115G>T | 3'UTR (SNP) | VAF 61/146 reads (42%) | called by muse, mutect2, varscan2
- TXNIP | c.*753_*779del | 3'UTR (DEL) | VAF 46/229 reads (20%) | called by mutect2, pindel, varscan2
- UGGT1 | c.*2533T>A | 3'UTR (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- USP45 | c.*27C>G | 3'UTR (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- XKR6 | c.764+5640C>T | Intron (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- ZBTB17 | c.1459+20_1459+28dup | Intron (INS) | VAF 24/89 reads (27%) | catalogued as rs1422171970; called by mutect2, varscan2
- ZDHHC22 | c.*220C>T | 3'UTR (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- ZIC4 | c.-15-1336C>G | Intron (SNP) | VAF 24/74 reads (32%) | catalogued as COSV67172472; called by muse, mutect2
- ZNF525 | c.*56A>T | 3'UTR (SNP) | VAF 175/614 reads (29%) | called by muse, mutect2, varscan2
- ZNF717 | c.*503A>G | 3'UTR (SNP) | VAF 47/66 reads (71%) | called by muse, mutect2, varscan2
- ZNF84 | c.*3148G>C | 3'UTR (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- ZSWIM9 | c.1855-101G>A | Intron (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2
